Somatic mutation profile of tumor specimen TCGA-VQ-A8E2-01A (aliquot TCGA-VQ-A8E2-01A-11D-A364-08) from TCGA case TCGA-VQ-A8E2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 57.8 years (21,112 days).
Specimen TCGA-VQ-A8E2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 133c6585-d22c-4971-9ad5-863c9f1b57aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8E2-10A (Blood Derived Normal), aliquot TCGA-VQ-A8E2-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2db2838c-4497-40a4-852a-73795bc5985f

The open-access MAF lists 121 somatic variants for this specimen: 94 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 25, Frame Shift Ins 3, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 32/106 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779406344, COSV55215056; called by muse, mutect2, varscan2
- ATRN | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV99497653; called by muse, mutect2
- BCAM | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs144233028, COSV54305476; called by muse, mutect2, varscan2
- CADM1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs768807528, COSV59002182; called by muse, mutect2, varscan2
- CASP9 | c.409G>A p.G137S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs771847429, COSV100423906; called by muse, mutect2, varscan2
- CBX6 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs930487149, COSV99328183; called by muse, mutect2, varscan2
- CELF4 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs150441111, COSV100612162; called by muse, mutect2, varscan2
- CFAP47 | c.5504T>G p.L1835R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100545611; called by muse, mutect2, varscan2
- CFAP69 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV60189610; called by muse, mutect2, varscan2
- CLP1 | c.1082T>C p.M361T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs890278391, COSV100239889; called by muse, mutect2, varscan2
- CNTNAP5 | c.691T>G p.L231V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70512606; called by muse, mutect2
- DAB2IP | c.442G>A p.D148N (on ENST00000408936; = p.D120N on NM_032552.3) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99406085; called by muse, mutect2
- DAPK3 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs745312042, COSV100009842; called by muse, mutect2, varscan2
- DDX4 | c.1412C>G p.S471* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs1245621804, COSV100737685; called by muse, mutect2, varscan2
- DEAF1 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs751558688, COSV100102254; called by muse, mutect2, varscan2
- DLC1 | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs777668661, COSV99364696; called by muse, mutect2, varscan2
- DNAAF3 | c.1451A>G p.E484G (on ENST00000524407 / NM_001256715.2; = p.E531G on NM_178837.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100787973; called by muse, mutect2, varscan2
- ECT2L | c.462G>C p.W154C | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV100872114; called by muse, mutect2, varscan2
- EFCAB7 | c.658G>C p.D220H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100937722; called by muse, mutect2, varscan2
- EPPK1 | c.5573A>C p.D1858A | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101599923; called by muse, mutect2
- FAM47C | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs149671724, COSV63725620; called by muse, mutect2, varscan2
- FCSK | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851157; called by muse, mutect2, varscan2
- FMN2 | c.3376G>A p.G1126R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as rs554573414, COSV60417116; called by muse, mutect2
- FMO1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs28360433; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.121); catalogued as COSV100437524; called by muse, mutect2, varscan2
- GNPTAB | c.3350G>A p.G1117E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV100172276; called by muse, mutect2, varscan2
- GTF2H4 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV99462077; called by muse, mutect2, varscan2
- H3C7 | c.358A>C p.I120L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as rs1336450196, COSV99769198; called by muse, mutect2, varscan2
- HNRNPL | c.1655A>G p.K552R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV99670492; called by muse, mutect2, varscan2
- HOXB3 | c.19T>C p.Y7H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100290773; called by muse, mutect2, varscan2
- INSRR | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs756026000, COSV100947905, COSV63874975; called by muse, mutect2
- IPO7 | c.2696A>C p.E899A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV101121840; called by muse, mutect2
- KIF6 | c.2049A>C p.E683D | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.07); catalogued as COSV54665979, COSV99760100; called by muse, mutect2, varscan2
- KMT2E | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777952395, COSV99996741; called by muse, mutect2, varscan2
- KRTAP8-1 | c.78C>G p.S26R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100297813, COSV100297855; called by muse, mutect2, varscan2
- L3MBTL3 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.608); catalogued as rs1344996050, COSV100696325; called by muse, mutect2
- LAMA5 | c.4378C>T p.H1460Y | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99441510; called by muse, mutect2, varscan2
- LCP2 | c.732T>G p.D244E | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.524); catalogued as COSV99253292; called by muse, mutect2
- LTF | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as rs776865450, COSV51606041; called by muse, mutect2, varscan2
- MACC1 | c.1123T>A p.Y375N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100256114, COSV60545507; called by muse, mutect2, varscan2
- MAP3K15 | c.1816T>G p.Y606D | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.567); catalogued as COSV100135354; called by muse, mutect2, varscan2
- MAP6 | c.2066A>C p.E689A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.162); catalogued as COSV100496841; called by muse, mutect2, varscan2
- MYH7 | c.2474A>T p.K825M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100805595; called by muse, mutect2, varscan2
- MYOCD | c.863G>C p.R288P | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58505663; called by muse, mutect2, varscan2
- MYOG | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as rs1340969960, COSV99614022; called by muse, mutect2, varscan2
- NEXMIF | c.165A>C p.K55N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as COSV99281477; called by muse, mutect2, varscan2
- NEXN | c.1376C>G p.S459C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57356599; called by muse, mutect2
- NTNG1 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV99638805; called by muse, mutect2, varscan2
- OR5D14 | c.508T>G p.F170V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59456459; called by muse, mutect2, varscan2
- OR8K5 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV100537272; called by muse, mutect2, varscan2
- PAPPA | c.3314C>T p.T1105M | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1472615793, COSV60278457, COSV60288225; called by muse, mutect2, varscan2
- PCDH17 | c.1127T>A p.V376D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100931815; called by muse, mutect2, varscan2
- PCDHB2 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.258); catalogued as COSV50564910, COSV50573455; called by muse, varscan2
- PCDHGA8 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.014); catalogued as rs989814835, COSV53902752; called by muse, mutect2
- PDE3B | c.980T>C p.M327T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99963011; called by muse, mutect2
- PGS1 | c.1277G>A p.G426D | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99428438; called by muse, mutect2, varscan2
- PIKFYVE | c.5011A>G p.I1671V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100011219; called by muse, mutect2, varscan2
- PSG6 | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99414388; called by muse, mutect2, varscan2
- RFC2 | c.983C>T p.A328V (on ENST00000055077 / NM_181471.3; = p.A294V on NM_002914.4) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs41272921; called by muse, mutect2
- RNF10 | c.254G>C p.S85T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100378865; called by muse, mutect2, varscan2
- RPTN | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 73/635 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100285658; called by muse, mutect2, varscan2
- RTN2 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.832); catalogued as rs774982121, COSV55594165; called by muse, mutect2, varscan2
- RYR3 | c.13625C>T p.P4542L (on ENST00000389232; = p.P4543L on NM_001036.6) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as rs1325751097, COSV66799722; called by muse, mutect2, varscan2
- SEMA6A | c.2108C>T p.T703I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99145890; called by muse, varscan2
- SLAMF7 | c.719T>G p.L240R | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100833345; called by muse, mutect2, varscan2
- SLC25A38 | c.713C>A p.A238E | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56195487, COSV99827916; called by muse, mutect2
- SLC49A4 | c.833+2T>C p.X278_splice | Splice Site (SNP) | VAF 34/92 reads (37%) | catalogued as COSV99659200; called by muse, mutect2, varscan2
- SMO | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV99976949; called by muse, mutect2, varscan2
- SOS1 | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101217176; called by muse, mutect2, varscan2
- SPINDOC | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.095); catalogued as COSV99588752; called by muse, mutect2, varscan2
- SPTA1 | c.5999A>T p.H2000L | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100935340; called by muse, mutect2
- SRGAP3 | c.841T>G p.F281V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV64531263; called by muse, mutect2
- TANC1 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs372287259; called by muse, mutect2, varscan2
- TCHH | c.4250G>A p.R1417H | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.912); catalogued as rs370960477, COSV64274616; called by muse, mutect2, varscan2
- TLE1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1217423158, COSV100916009; called by muse, mutect2, varscan2
- TMEM38B | c.286dup p.C96Lfs*4 | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs756048916; called by mutect2, varscan2
- TRO | c.1094A>G p.Q365R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV99437010; called by muse, mutect2, varscan2
- TROAP | c.2055del p.I686Sfs*7 | Frame Shift Del (DEL) | VAF 44/145 reads (30%) | catalogued as rs753006677; called by mutect2, pindel, varscan2
- TRRAP | c.11349A>C p.K3783N (on ENST00000359863 / NM_001244580.1; = p.K3754N on NM_003496.3) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV100705473; called by muse, mutect2
- TSACC | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100966221, COSV100966228; called by muse, mutect2, varscan2
- UROC1 | c.944A>G p.H315R | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.783); catalogued as COSV99332116; called by muse, mutect2
- USP34 | c.4390G>C p.D1464H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV101277139; called by muse, mutect2, varscan2
- VDAC3 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99195130; called by muse, mutect2
- WNT3A | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99469951; called by muse, mutect2, varscan2
- XPO5 | c.3471C>G p.C1157W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99541255; called by muse, mutect2
- XRCC5 | c.888C>G p.C296W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV101079775; called by muse, mutect2, varscan2
- ZNF235 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs765611478, COSV99349651; called by muse, mutect2, varscan2
- ZNF257 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV101448149; called by muse, mutect2, varscan2
- ZNF385D | c.910T>G p.Y304D | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99875853; called by muse, mutect2
- DNAH11 | c.10102_10129del p.E3368Nfs*2 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SCN10A | c.614_615dup p.I206Qfs*2 | Frame Shift Ins (INS) | VAF 8/70 reads (11%) | called by mutect2, pindel, varscan2
- SLC7A6 | c.785dup p.N262Kfs*39 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- ADRA2C | c.468C>T p.A156= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1169860571, COSV100342764; called by muse, mutect2, varscan2
- AHNAK | c.10698C>T p.P3566= | Silent (SNP) | VAF 52/182 reads (29%) | catalogued as COSV99948893; called by muse, mutect2, varscan2
- APOB | c.10980C>T p.D3660= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99267096; called by muse, mutect2, varscan2
- BATF2 | c.171C>T p.L57= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs754654435, COSV100101847; called by muse, mutect2, varscan2
- COL7A1 | c.4839A>T p.G1613= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100097173; called by muse, mutect2, varscan2
- CWH43 | c.1860G>C p.L620= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as COSV99892939, COSV99893807; called by muse, mutect2
- DNAH3 | c.3561C>T p.S1187= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs1272075904, COSV99769543; called by muse, mutect2, varscan2
- GRM1 | c.432C>G p.G144= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV99265912; called by muse, mutect2
- IFT80 | c.216G>A p.K72= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as COSV100425012, COSV58446616; called by muse, mutect2, varscan2
- IL16 | c.1350C>G p.L450= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57263355; called by muse, mutect2
- MRPL36 | c.90A>G p.L30= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs749561344, COSV56876308; called by muse, mutect2, varscan2
- MYCBP2 | c.11430T>C p.N3810= (on ENST00000357337; = p.N3848= on NM_015057.5) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100631274; called by muse, mutect2, varscan2
- NCAPD3 | c.1818C>A p.L606= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV101599385, COSV73258379; called by muse, mutect2, varscan2
- NUP205 | c.3852G>A p.E1284= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99607379; called by muse, mutect2
- PCDHGA2 | c.1755C>T p.G585= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV53925240; called by muse, mutect2
- PHYKPL | c.222G>A p.Q74= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100069648; called by muse, mutect2, varscan2
- SCN5A | c.993C>T p.D331= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs757715398, COSV100349865; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC39A10 | c.1752T>C p.D584= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100660726; called by muse, mutect2, varscan2
- SMOC1 | c.1131C>T p.N377= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs773345519, COSV100734595; called by muse, mutect2, varscan2
- SPTBN1 | c.2064C>T p.S688= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs749471660, COSV100443162; called by muse, mutect2, varscan2
- TNS1 | c.3285G>A p.S1095= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs375025312, COSV99410462; called by muse, mutect2, varscan2
- TOGARAM1 | c.783C>G p.A261= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100753211; called by muse, mutect2, varscan2
- UPK3A | c.744C>T p.S248= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs1289099533, COSV99343198; called by muse, mutect2, varscan2
- USP33 | c.1272G>A p.Q424= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100657186, COSV100657202; called by muse, mutect2, varscan2
- ZNF451 | c.1563C>T p.H521= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs143799111; called by muse, mutect2
- CACNA1B | c.5223-1569G>A | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as rs777767652, COSV53115208; called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640806 G>A | 3'Flank (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99194856; called by muse, mutect2, varscan2
